Somatic mutation profile of tumor specimen TCGA-XK-AAIR-01A (aliquot TCGA-XK-AAIR-01A-11D-A41K-08) from TCGA case TCGA-XK-AAIR, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 75.8 years (27,703 days).
Specimen TCGA-XK-AAIR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1365c32a-dd22-43f1-8be2-35e5b13c2c57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XK-AAIR-10A (Blood Derived Normal), aliquot TCGA-XK-AAIR-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3941d273-0f95-49a7-a700-5c99e3d6890c

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Splice Site 1, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.2782T>G p.Y928D | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99286753; called by muse, mutect2
- AMZ2 | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.478); catalogued as rs1555742511, COSV100703220; called by muse, mutect2, varscan2
- CNTROB | c.1886T>G p.V629G | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as COSV100972757; called by muse, mutect2
- CREB3L4 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV99665824, COSV99665847; called by muse, mutect2, varscan2
- FRMD6 | c.784T>G p.L262V (on ENST00000344768 / NM_001267046.2; = p.L254V on NM_152330.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100656248; called by muse, mutect2, varscan2
- HSPA8 | c.801T>G p.C267W | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99914597; called by muse, mutect2, varscan2
- KCNQ2 | c.769del p.E257Rfs*16 | Frame Shift Del (DEL) | VAF 33/206 reads (16%) | catalogued as COSV60437806; called by mutect2, pindel, varscan2
- KIF26B | c.5339C>T p.T1780M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1367603873, COSV63644879; called by muse, mutect2
- LHX9 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100436058, COSV61328079; called by muse, mutect2, varscan2
- M1AP | c.1514A>C p.K505T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99284189; called by muse, mutect2, varscan2
- MYO15A | c.6256G>A p.V2086M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs369781492; called by muse, mutect2, varscan2
- PDYN | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377075531, COSV54100958; called by muse, mutect2, varscan2
- RBM45 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV99617995; called by muse, mutect2, varscan2
- TRIP12 | c.3399+1del p.X1133_splice | Splice Site (DEL) | VAF 7/50 reads (14%) | catalogued as COSV52266391; called by mutect2, pindel, varscan2
- USP6 | c.2135C>A p.P712Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100004828; called by muse, mutect2
- SYNE1 | c.8266dup p.I2756Nfs*19 (on ENST00000367255 / NM_182961.4; = p.I2763Nfs*19 on NM_033071.3) | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by pindel, varscan2
- WIPF2 | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); called by muse, mutect2
- MAGI2 | c.1254C>A p.S418= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100836382; called by muse, mutect2, varscan2
- MTHFD1L | c.936C>T p.L312= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100943534; called by muse, mutect2, varscan2
- SI | c.3201C>A p.I1067= | Silent (SNP) | VAF 5/107 reads (5%) | catalogued as COSV100016952, COSV52279054; called by muse, mutect2
- SIRPB2 | c.510G>T p.G170= | Silent (SNP) | VAF 5/54 reads (9%) | catalogued as COSV100708621; called by muse, mutect2, varscan2
- SORCS3 | c.3528C>T p.N1176= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs909047082, COSV100865631; called by muse, mutect2
- MC2R | c.892_894dup | 3'UTR (INS) | VAF 5/41 reads (12%) | called by mutect2, pindel, varscan2
